Somatic mutation profile of tumor specimen TCGA-CJ-4907-01A (aliquot TCGA-CJ-4907-01A-01D-1429-08) from TCGA case TCGA-CJ-4907, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 58.1 years (21,208 days).
Specimen TCGA-CJ-4907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa7bd50d-6858-4d5e-8007-37b3fe0dc73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4907-11A (Solid Tissue Normal), aliquot TCGA-CJ-4907-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574c803f-414b-4872-84c2-234309c36bd0

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 37, Silent 15, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4448G>T p.C1483F | Missense Mutation (SNP) | VAF 14/378 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs786205165, CM1412980, CM153079, COSV63869079, COSV63869516; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PAH | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 49/182 reads (27%) | catalogued as rs398123294, COSV61014561; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATF6B | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV64322343; called by muse, mutect2
- CDKL4 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs779299787, COSV101115325; called by muse, mutect2, varscan2
- CNKSR3 | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 31/183 reads (17%) | catalogued as COSV70480816; called by muse, mutect2, varscan2
- CNOT4 | c.1123A>G p.T375A (on ENST00000315544 / NM_001190848.1; = p.T372A on NM_013316.4) | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59650462; called by muse, mutect2, varscan2
- CNTN5 | c.1412C>A p.A471D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54289091; called by muse, mutect2, varscan2
- COL25A1 | c.1197G>A p.K399= | Splice Region (SNP) | VAF 75/483 reads (16%) | catalogued as rs755738364, COSV67647436; called by muse, mutect2, varscan2
- CSMD1 | c.3295C>T p.P1099S (on ENST00000520002; = p.P1098S on NM_033225.6) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59292378; called by muse, mutect2
- CTNND1 | c.1888T>C p.S630P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV62382439; called by muse, mutect2, varscan2
- DMXL1 | c.3040A>G p.N1014D | Missense Mutation (SNP) | VAF 139/311 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60706308; called by muse, mutect2, varscan2
- DTNBP1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as rs1415761555, COSV59038291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM160B1 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV65086297; called by muse, mutect2
- FAT2 | c.5508C>G p.F1836L | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV55815056; called by muse, mutect2, varscan2
- FLRT2 | c.1661T>C p.V554A | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV58137656; called by muse, mutect2
- GCC2 | c.4735C>G p.L1579V | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59174526; called by muse, mutect2, varscan2
- KAT7 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52013419; called by muse, mutect2, varscan2
- LAMC3 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs775368834, COSV63089148; called by muse, varscan2
- LOXL1 | c.1427A>G p.H476R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56093712; called by muse, mutect2, varscan2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, mutect2
- MAP3K4 | c.3222G>T p.M1074I | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV62330754; called by muse, mutect2, varscan2
- MORN5 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762113900, COSV65648618; called by muse, mutect2
- MTSS1 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1197259244, COSV52674472; called by mutect2, varscan2
- MTUS2 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as COSV70913950, COSV70914558; called by muse, mutect2, varscan2
- NEURL1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV63913858; called by muse, mutect2, varscan2
- NPNT | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs780911808, COSV59752349; called by muse, mutect2, varscan2
- OAS1 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV52534130, COSV52534460; called by muse, mutect2, varscan2
- PABPC1 | c.1427T>A p.V476D | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV59399182; called by muse, mutect2, varscan2
- PIK3C3 | c.559A>T p.M187L | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV56276706; called by muse, mutect2, varscan2
- PIWIL1 | c.1685del p.S562Ifs*30 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | catalogued as COSV55353814; called by mutect2, pindel, varscan2
- PLEKHM2 | c.2530A>C p.I844L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.333); catalogued as COSV53816267; called by muse, mutect2, varscan2
- PPFIBP2 | c.1529C>T p.T510I | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55074996; called by muse, mutect2, varscan2
- PSKH2 | c.1136C>A p.S379* | Nonsense Mutation (SNP) | VAF 25/175 reads (14%) | catalogued as COSV52609191, COSV52609532; called by muse, mutect2, varscan2
- RBFOX1 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766300841, COSV60947401; called by muse, mutect2, varscan2
- RYR3 | c.13375G>A p.A4459T (on ENST00000389232; = p.A4460T on NM_001036.6) | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV66780793; called by muse, mutect2, varscan2
- S1PR4 | c.1131C>A p.S377R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55739646; called by muse, mutect2
- STK10 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV51571290, COSV51573051; called by muse, mutect2, varscan2
- STRN3 | c.1856T>A p.L619* (on ENST00000357479 / NM_001083893.2; = p.L535* on NM_014574.4) | Nonsense Mutation (SNP) | VAF 21/157 reads (13%) | catalogued as COSV62578746; called by muse, mutect2, varscan2
- STT3B | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV55501540; called by muse, mutect2, varscan2
- SULT4A1 | c.239T>G p.M80R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV50780470; called by muse, mutect2, varscan2
- TAAR1 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs182617139, COSV51587886; called by muse, mutect2
- THSD7B | c.2476T>A p.C826S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55662503; called by muse, mutect2, varscan2
- UBE3C | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1393034393, COSV61951127; called by muse, mutect2, varscan2
- USF3 | c.5864C>A p.S1955Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs757795739, COSV57070589; called by muse, mutect2, varscan2
- ZCCHC9 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54175812; called by muse, mutect2, varscan2
- LRGUK | c.843_847del p.L282Efs*19 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | called by mutect2, pindel, varscan2
- MTOR | c.7289_7294del p.R2430_L2431del | In Frame Del (DEL) | VAF 12/117 reads (10%) | called by mutect2, pindel, varscan2
- MYEF2 | c.1475_1486del p.G492_L495del | In Frame Del (DEL) | VAF 32/209 reads (15%) | called by mutect2, pindel
- PLEKHH2 | c.2397del p.A800Lfs*15 | Frame Shift Del (DEL) | VAF 35/185 reads (19%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13650T>A p.T4550= | Silent (SNP) | VAF 55/416 reads (13%) | catalogued as COSV68944188, COSV68946595; called by muse, mutect2, varscan2
- ADH1B | c.114C>G p.R38= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV59295438; called by muse, mutect2, varscan2
- BRD8 | c.858T>A p.T286= (on ENST00000254900 / NM_139199.2; = p.T359= on NM_006696.4) | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV50145716; called by muse, mutect2, varscan2
- CCNA1 | c.1090C>T p.L364= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as COSV55220300, COSV55221623; called by muse, mutect2, varscan2
- CENPC | c.1158T>C p.A386= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1308282708, COSV56621702; called by muse, mutect2, varscan2
- CTCFL | c.1323C>T p.S441= | Silent (SNP) | VAF 105/340 reads (31%) | catalogued as rs748219015, COSV54771590; called by muse, mutect2, varscan2
- DRD5 | c.1260C>T p.P420= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs776161015, COSV58576998; called by muse, mutect2, varscan2
- EPHA8 | c.318C>T p.R106= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs1275281000, COSV51263927; called by muse, mutect2
- EXTL1 | c.1203C>T p.P401= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV100959126, COSV65337193; called by muse, mutect2, varscan2
- KCNA5 | c.1161C>T p.G387= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as rs922851359, COSV52904298; called by muse, mutect2
- OR2AE1 | c.390G>A p.L130= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as COSV60389800; called by muse, mutect2
- OSBPL5 | c.2580C>T p.S860= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV55140016; called by muse, mutect2
- PREX1 | c.3729G>T p.R1243= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV64248730; called by muse, mutect2, varscan2
- PTPRS | c.3864G>C p.G1288= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV53612620; called by muse, mutect2, varscan2
- TAS1R3 | c.1017G>A p.K339= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs760096202, COSV59562467; called by muse, mutect2, varscan2
